Somatic mutation profile of tumor specimen TCGA-GS-A9TW-01A (aliquot TCGA-GS-A9TW-01A-11D-A382-10) from TCGA case TCGA-GS-A9TW, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mediastinal (thymic) large B-cell lymphoma; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 23.3 years (8,493 days).
Specimen TCGA-GS-A9TW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88abea19-19d5-481c-8c67-a02338e3fd39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GS-A9TW-10A (Blood Derived Normal), aliquot TCGA-GS-A9TW-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66a24ebf-5c77-44e0-a4f6-9009a7cd851d

The open-access MAF lists 303 somatic variants for this specimen: 222 protein-altering or splice-affecting, 76 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 76, Nonsense Mutation 14, Frame Shift Del 7, In Frame Del 4, Splice Site 4, Frame Shift Ins 3, Intron 3, Splice Region 3, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 81/263 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs143703625, COSV55114356; called by muse, mutect2, varscan2
- AASS | c.2076del p.P693Qfs*3 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | catalogued as rs768943469; called by mutect2, pindel, varscan2
- ABCB8 | c.1169T>G p.V390G (on ENST00000297504 / NM_001282291.2; = p.V373G on NM_007188.5) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99874383; called by muse, mutect2, varscan2
- ABHD12B | c.473T>G p.L158R (on ENST00000337334 / NM_001206673.2; = p.L81R on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1187457861, COSV100485670; called by muse, mutect2, varscan2
- ABHD2 | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.379); catalogued as COSV100756280; called by muse, mutect2, varscan2
- ABI1 | c.1157A>G p.Q386R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100697880; called by muse, mutect2
- ABLIM3 | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as rs753335721, COSV100448399; called by muse, mutect2, varscan2
- ABT1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV99223217; called by muse, mutect2, varscan2
- ACSL3 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 116/498 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100657940; called by muse, mutect2, varscan2
- ADGRB3 | c.4471G>A p.E1491K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0.108); catalogued as COSV53233435, COSV53251473; called by muse, mutect2, varscan2
- ADGRV1 | c.17746T>C p.C5916R | Missense Mutation (SNP) | VAF 112/218 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101315941; called by muse, mutect2, varscan2
- ALX1 | c.415T>G p.F139V | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100374409; called by muse, mutect2
- AR | c.2272G>C p.V758L | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV101018248, COSV65955730; called by muse, mutect2, varscan2
- ASAP1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100727267; called by muse, mutect2, varscan2
- ASIC5 | c.1156A>C p.I386L | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV101611136; called by muse, mutect2, varscan2
- ASXL3 | c.5249T>A p.V1750E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV99324880; called by muse, mutect2, varscan2
- ATP10B | c.2348G>A p.G783D | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs979500913, COSV100514949; called by muse, mutect2, varscan2
- ATP5MC1 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100582386; called by muse, varscan2
- ATR | c.960G>T p.M320I | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV100638228; called by muse, mutect2, varscan2
- AVIL | c.1750G>T p.E584* | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | catalogued as COSV57683626, COSV99142376; called by muse, mutect2, varscan2
- BAIAP2L1 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 55/325 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.817); catalogued as COSV50056204, COSV99134141; called by muse, mutect2, varscan2
- BCL9L | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as rs775902823, COSV99419251; called by muse, mutect2, varscan2
- C18orf54 | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100266515; called by muse, mutect2, varscan2
- C1orf112 | c.2394C>A p.F798L | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99609779; called by muse, mutect2, varscan2
- CACNA1D | c.4506C>A p.H1502Q (on ENST00000350061 / NM_001128840.3; = p.H1522Q on NM_000720.4) | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99858159; called by muse, mutect2, varscan2
- CACNA1H | c.5687C>T p.A1896V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs139080716, COSV99326720; called by muse, mutect2, varscan2
- CACNA2D2 | c.2228G>A p.R743H (on ENST00000479441 / NM_001174051.3; = p.R736H on NM_006030.4) | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.583); catalogued as rs768385122, COSV99817630; called by muse, mutect2, varscan2
- CALHM5 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.847); catalogued as rs571775020, COSV62068805; called by muse, mutect2, varscan2
- CAMK2G | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99989806; called by muse, mutect2, varscan2
- CARD9 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs757745178, COSV100261187; called by muse, mutect2, varscan2
- CBFA2T3 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99241818; called by muse, mutect2, varscan2
- CCSER1 | c.1175G>A p.R392K | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100391534; called by muse, mutect2, varscan2
- CD2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV101040395, COSV101040419; called by muse, varscan2
- CDH2 | c.2215G>T p.V739L | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.991); catalogued as rs753513462, COSV99296883; called by muse, mutect2, varscan2
- CDKL1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766725239, COSV53581477, COSV99367465; called by muse, mutect2, varscan2
- CEP85 | c.1859G>T p.R620L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV99432244; called by muse, mutect2, varscan2
- CHD3 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as rs143327592; called by muse, mutect2, varscan2
- CHEK2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV60423157; called by muse, varscan2
- CHEK2 | c.291_292insAT p.A98Mfs*40 (on ENST00000382580 / NM_001005735.2; = p.A98Mfs*13 on NM_007194.4) | Frame Shift Ins (INS) | VAF 16/74 reads (22%) | catalogued as COSV100101650; called by pindel, varscan2
- CLEC7A | c.382G>T p.E128* (on ENST00000304084 / NM_197947.3; = p.E82* on NM_022570.5) | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100021158, COSV53721455; called by muse, mutect2, varscan2
- CLMN | c.1817G>C p.G606A | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV100112390; called by muse, mutect2, varscan2
- CLTB | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV100124975; called by muse, mutect2, varscan2
- COL14A1 | c.1106T>G p.F369C | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99919264; called by muse, varscan2
- CRLF3 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1222089729, COSV60836318; called by muse, mutect2, varscan2
- CTRC | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV101036363, COSV101036407; called by muse, mutect2, varscan2
- CTTNBP2 | c.3055A>C p.N1019H | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99353925; called by muse, mutect2, varscan2
- CX3CL1 | c.1059C>G p.F353L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99136332; called by muse, mutect2, varscan2
- DCLK1 | c.942T>C p.V314= | Splice Region (SNP) | VAF 20/77 reads (26%) | catalogued as COSV99711138; called by muse, mutect2, varscan2
- DCSTAMP | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs139698540; called by muse, mutect2, varscan2
- DNAH10 | c.7976C>T p.S2659L (on ENST00000409039; = p.S2598L on NM_207437.3) | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV101292247; called by muse, mutect2, varscan2
- DNAJC7 | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100347798; called by muse, mutect2, varscan2
- DOK5 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV52817455, COSV99373860; called by muse, mutect2, varscan2
- DPYD | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100032247; called by muse, mutect2, varscan2
- DSCC1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs149934159; called by muse, mutect2, varscan2
- DTX3L | c.1660G>C p.D554H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV99950033; called by muse, mutect2, varscan2
- DUSP16 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs369986596; called by muse, mutect2, varscan2
- EDA | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.529); catalogued as CM133818, COSV100999990, COSV65782006; called by muse, mutect2, varscan2
- EDRF1 | c.2171-1G>A p.X724_splice (on ENST00000356792 / NM_001202438.2; = p.X690_splice on NM_015608.2) | Splice Site (SNP) | VAF 49/200 reads (25%) | catalogued as COSV100523477, COSV100524081; called by muse, mutect2, varscan2
- EGR1 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV99525437; called by muse, varscan2
- EIF3L | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.859); catalogued as COSV101094526; called by muse, mutect2, varscan2
- EMC1 | c.1678T>A p.Y560N | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV100916443; called by muse, varscan2
- ENOSF1 | c.449G>T p.R150I (on ENST00000340116 / NM_001354066.2; = p.R102I on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV99201068, COSV99201126; called by muse, mutect2, varscan2
- EPC2 | c.846C>G p.I282M | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV99309560; called by muse, mutect2, varscan2
- ESRP1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64412226; called by muse, mutect2, varscan2
- EVC | c.2781A>G p.L927= | Splice Region (SNP) | VAF 14/48 reads (29%) | catalogued as rs777059868, COSV53838335, COSV99381739; called by muse, varscan2
- EXOC4 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs201300506; called by muse, mutect2, varscan2
- FAF2 | c.267+1G>A p.X89_splice | Splice Site (SNP) | VAF 43/102 reads (42%) | catalogued as COSV99990466; called by muse, mutect2, varscan2
- FAM120A | c.2491C>G p.Q831E | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.324); catalogued as COSV99465060, COSV99465142; called by muse, mutect2, varscan2
- FAM9A | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.049); catalogued as COSV101121342; called by muse, mutect2, varscan2
- FANCL | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99287577; called by muse, mutect2, varscan2
- FREM1 | c.4853T>G p.I1618S | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101084504; called by muse, mutect2
- FRMD4B | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | catalogued as rs773566028, COSV101273452; called by muse, mutect2, varscan2
- GABRQ | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV64784677; called by muse, mutect2, varscan2
- GPR84 | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99910033; called by mutect2, varscan2
- GRIN2C | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs539229067, COSV99500980; called by muse, mutect2, varscan2
- GTDC1 | c.263A>T p.Y88F | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99600382; called by muse, mutect2, varscan2
- H3C4 | c.260G>C p.S87T | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); catalogued as rs771901563, COSV61911502, COSV61911774; called by muse, mutect2, varscan2
- H4-16 | c.172G>C p.V58L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100797640; called by muse, mutect2, varscan2
- HKDC1 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs774349922, COSV100664546; called by muse, mutect2, varscan2
- HOXC13 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as COSV99673395; called by muse, mutect2, varscan2
- HSPA14 | c.520T>C p.S174P | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV101000666; called by muse, mutect2, varscan2
- IGKV1-12 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs753362888; called by muse, mutect2, varscan2
- IGLV3-25 | c.159G>C p.W53C | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372042849; called by muse, mutect2, varscan2
- ILK | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs768217957, COSV54450343; called by muse, mutect2, varscan2
- IMPG1 | c.1670A>G p.Q557R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs963852045, COSV100886384; called by muse, mutect2
- INTS7 | c.2405C>G p.T802S | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100877491; called by muse, mutect2, varscan2
- IRX2 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV100121720; called by muse, mutect2, varscan2
- ITPKB | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.009); catalogued as rs950463843, COSV99684328; called by muse, mutect2, varscan2
- JARID2 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100521874; called by muse, mutect2, varscan2
- JMJD1C | c.3738A>T p.E1246D | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100550546; called by muse, mutect2, varscan2
- KCNH8 | c.442+2T>C p.X148_splice | Splice Site (SNP) | VAF 38/124 reads (31%) | catalogued as COSV100109785; called by muse, mutect2, varscan2
- KCTD19 | c.2284A>G p.K762E | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100430921; called by muse, mutect2
- KCTD20 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as rs750377572, COSV54803047; called by muse, mutect2, varscan2
- KMT2C | c.3850G>A p.G1284R | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100071769; called by muse, mutect2, varscan2
- LAMA5 | c.2806A>G p.N936D | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as COSV99439999; called by muse, mutect2
- LEPR | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs754264793, COSV100848177, COSV62752998; called by muse, mutect2, varscan2
- LMAN1L | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100547702; called by muse, mutect2, varscan2
- LRRC23 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782748706, COSV50386825; called by muse, mutect2, varscan2
- LRRN1 | c.1909G>C p.G637R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100076280; called by muse, mutect2
- MAGEC3 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs752805585, COSV100025379; called by muse, mutect2, varscan2
- MAGI1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770193154, COSV58322664; called by muse, mutect2, varscan2
- MCF2 | c.587T>G p.V196G | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV100644772, COSV58496570; called by muse, varscan2
- MCM7 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as rs1481354122, COSV100384903; called by muse, mutect2, varscan2
- MET | c.3576G>A p.M1192I | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59257232; called by muse, mutect2, varscan2
- METTL16 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV99563403; called by muse, mutect2, varscan2
- MINAR1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV59583912; called by muse, mutect2, varscan2
- MOB2 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs189715976, COSV100326533; called by mutect2, varscan2
- MSLN | c.1318A>G p.T440A (on ENST00000382862 / NM_013404.4; = p.T432A on NM_005823.6) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99558298; called by muse, mutect2, varscan2
- MTMR1 | c.744A>G p.I248M | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV100953096; called by muse, mutect2, varscan2
- MUSK | c.1306A>C p.K436Q | Missense Mutation (SNP) | VAF 87/304 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.272); catalogued as COSV99504183; called by muse, mutect2, varscan2
- MYT1L | c.1380C>G p.D460E | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV101220762; called by muse, mutect2, varscan2
- NBPF3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.852); catalogued as COSV100558765; called by muse, mutect2, varscan2
- NEBL | c.181T>C p.S61P | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV101012368; called by muse, mutect2, varscan2
- NFATC2IP | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1281650418, COSV100297570; called by muse, mutect2, varscan2
- NFYB | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 50/186 reads (27%) | catalogued as COSV99527176; called by muse, varscan2
- NT5DC3 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101230960; called by muse, mutect2, varscan2
- NUP98 | c.1655T>G p.L552R | Missense Mutation (SNP) | VAF 29/373 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100262365; called by muse, mutect2
- OBSCN | c.8873C>T p.S2958L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs973888849, COSV52784851, COSV99483230; called by muse, mutect2, varscan2
- OPRM1 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as rs766593040, COSV100001312; called by muse, mutect2, varscan2
- OPTN | c.1200T>G p.H400Q | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV99537149, COSV99537474; called by muse, mutect2, varscan2
- OR14J1 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1185139304, COSV101012778; called by muse, mutect2, varscan2
- OR56A3 | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.046); catalogued as COSV100290210, COSV61570212; called by muse, mutect2, varscan2
- P2RY8 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as rs1328381348, COSV101184021; called by muse, varscan2
- P2RY8 | c.764T>C p.F255S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV101184022; called by muse, varscan2
- PABPC3 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1220817963, COSV99879498; called by muse, mutect2, varscan2
- PCDH11X | c.3119A>T p.K1040I | Missense Mutation (SNP) | VAF 170/542 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as COSV100011675; called by muse, mutect2, varscan2
- PCDHA11 | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV56494142; called by muse, mutect2, varscan2
- PCLO | c.5361G>C p.K1787N | Missense Mutation (SNP) | VAF 96/329 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV100432527, COSV61613112; called by muse, mutect2
- PDE1B | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV99672529; called by muse, mutect2, varscan2
- PDP1 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | catalogued as rs202225648, COSV99892375; called by muse, mutect2, varscan2
- PGBD4 | c.1670A>G p.K557R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.194); catalogued as COSV99854865; called by muse, mutect2, varscan2
- PHF12 | c.738G>C p.K246N | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99255771; called by muse, mutect2, varscan2
- PINK1 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 39/143 reads (27%) | catalogued as COSV100387297; called by muse, mutect2, varscan2
- PLA2G2E | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100908813; called by muse, mutect2, varscan2
- PLCE1 | c.2155G>A p.G719S | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs771716896, COSV53376521; called by muse, mutect2, varscan2
- PLCG1 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV99718847; called by muse, mutect2, varscan2
- PNPLA5 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.688); catalogued as rs780690737, COSV53374564; called by muse, mutect2, varscan2
- POLR2J3 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758441868, COSV101028372, COSV65025726; called by muse, mutect2, varscan2
- PPWD1 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408350613, COSV51552810; called by muse, mutect2
- PRR12 | c.2821G>A p.G941R (on ENST00000615927; = p.G1762R on NM_020719.3) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs774514598, COSV101330670; called by mutect2, varscan2
- PTPRC | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 144/471 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100722642; called by muse, mutect2, varscan2
- PTPRR | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs771463912, COSV51744946; called by muse, mutect2, varscan2
- PWWP3A | c.115C>G p.L39V (on ENST00000627377; = p.L38V on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60900756; called by muse, mutect2, varscan2
- QRFPR | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749713097, COSV57676481; called by muse, mutect2
- RAB6B | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99557992; called by muse, mutect2, varscan2
- RAB9A | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99689703; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1891G>A p.G631S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.127); catalogued as rs1460099083, COSV54575962; called by muse, mutect2, varscan2
- REEP4 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100098145; called by muse, mutect2, varscan2
- RHOBTB2 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99310967; called by muse, varscan2
- RIMS1 | c.106A>G p.I36V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99326844; called by muse, mutect2, varscan2
- RNF212 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as rs1460980443, COSV61364858; called by muse, mutect2, varscan2
- RNPS1 | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100067422; called by muse, mutect2, varscan2
- RUNX3 | c.217A>T p.N73Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.407); catalogued as COSV100136857; called by muse, mutect2, varscan2
- SCN7A | c.1810T>A p.F604I | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV101313228; called by muse, mutect2, varscan2
- SCYL3 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs752839423, COSV100884292; called by muse, mutect2, varscan2
- SDHC | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as COSV100713664; called by muse, mutect2, varscan2
- SH3BP4 | c.2656G>T p.V886L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100749169; called by muse, mutect2, varscan2
- SH3RF3 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100512804, COSV58684112; called by muse, mutect2, varscan2
- SLC12A9 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs760730107, COSV99307816; called by muse, mutect2, varscan2
- SLC20A1 | c.245G>C p.S82T | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV99734065; called by muse, mutect2, varscan2
- SLC25A47 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749753667, COSV100690123, COSV100690166; called by muse, mutect2, varscan2
- SLC26A7 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 118/437 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV99403333; called by muse, mutect2, varscan2
- SLC32A1 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1267757229, COSV99462227; called by muse, mutect2, varscan2
- SLC35F1 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100837347; called by muse, mutect2
- SLITRK5 | c.415A>C p.N139H | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280742; called by muse, mutect2, varscan2
- SMC2 | c.1348G>T p.A450S | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV99658957; called by muse, mutect2, varscan2
- SMURF1 | c.405C>G p.V135= | Splice Region (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100742457; called by muse, mutect2, varscan2
- SOX18 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV100450546, COSV61110367; called by mutect2, varscan2
- SPRED2 | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV100710218; called by muse, mutect2, varscan2
- SPTA1 | c.3246T>A p.Y1082* | Nonsense Mutation (SNP) | VAF 21/150 reads (14%) | catalogued as COSV100934919; called by muse, mutect2, varscan2
- SRM | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100978950; called by muse, mutect2, varscan2
- STAP2 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as COSV101654917; called by muse, mutect2, varscan2
- STK3 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 32/391 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV101372527, COSV69223546; called by muse, mutect2
- SWAP70 | c.1277A>G p.Y426C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100013772; called by muse, mutect2, varscan2
- SYNGR2 | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99857229; called by muse, mutect2, varscan2
- TAS2R1 | c.463T>G p.F155V | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV101225765; called by muse, mutect2
- TGS1 | c.1975G>C p.D659H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52703627, COSV99485395; called by muse, mutect2, varscan2
- THBS4 | c.2678A>G p.Y893C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644268; called by muse, mutect2, varscan2
- TMEM131L | c.3310C>A p.L1104I | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV99547406; called by muse, mutect2, varscan2
- TMEM201 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs536284149, COSV100440419; called by muse, mutect2, varscan2
- TMEM245 | c.1283T>G p.V428G | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV101002318; called by muse, mutect2, varscan2
- TNPO1 | c.1938A>C p.K646N | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100473408; called by muse, mutect2, varscan2
- TNRC6A | c.3338C>A p.A1113E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100170000; called by muse, mutect2, varscan2
- TPR | c.3358G>A p.A1120T | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.145); catalogued as rs1436839066, COSV100823923; called by muse, mutect2, varscan2
- TRIM25 | c.1673T>A p.I558N | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100380991; called by muse, mutect2, varscan2
- TRMT5 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99712120; called by muse, mutect2, varscan2
- TTF1 | c.2337T>A p.D779E | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as COSV100524693; called by muse, mutect2, varscan2
- TULP4 | c.2372G>C p.G791A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV100893495; called by muse, varscan2
- UACA | c.1947dup p.L650Ifs*9 | Frame Shift Ins (INS) | VAF 112/371 reads (30%) | catalogued as rs761196686; called by mutect2, varscan2
- UBB | c.73A>T p.N25Y | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100141644; called by muse, mutect2, varscan2
- USP24 | c.6886G>A p.G2296R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as COSV99599698; called by muse, mutect2, varscan2
- USP24 | c.4330G>A p.G1444R | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769403889, COSV99599701; called by muse, mutect2, varscan2
- UVSSA | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs773114843, COSV66230232; called by mutect2, varscan2
- XBP1 | c.716T>G p.V239G | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV99321653; called by muse, mutect2, varscan2
- YES1 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100099556; called by muse, mutect2
- ZBTB40 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1258977668, COSV100988798; called by muse, mutect2, varscan2
- ZC3H7A | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs747086458, COSV100865518; called by muse, varscan2
- ZCCHC8 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs759328784, COSV100288664; called by muse, mutect2, varscan2
- ZFC3H1 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 112/360 reads (31%) | catalogued as COSV66430431; called by muse, mutect2, varscan2
- ZNF160 | c.341A>G p.H114R | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100762330; called by muse, mutect2, varscan2
- ZNF217 | c.1130G>A p.C377Y | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184461; called by muse, mutect2, varscan2
- ZNF266 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV100749384, COSV100749415; called by muse, mutect2, varscan2
- ZNF439 | c.1256T>C p.F419S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100397479; called by muse, mutect2, varscan2
- ZNF501 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.958); catalogued as COSV101247102; called by muse, mutect2, varscan2
- ZNF708 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 28/188 reads (15%) | catalogued as rs1568344100, COSV63608806; called by muse, mutect2, varscan2
- ZSCAN20 | c.2341C>T p.L781F | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV100792599; called by muse, mutect2, varscan2
- APOB | c.3095_3096delinsG p.T1032Sfs*2 | Frame Shift Del (DEL) | VAF 40/160 reads (25%) | called by pindel, varscan2*
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by pindel, varscan2
- C4orf17 | c.879_880+6del p.X293_splice | Splice Site (DEL) | VAF 35/112 reads (31%) | called by mutect2, pindel, varscan2
- IFIH1 | c.1056dup p.A353Sfs*3 | Frame Shift Ins (INS) | VAF 85/326 reads (26%) | called by mutect2, pindel, varscan2
- LRP2 | c.9953_9955del p.F3318del | In Frame Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.1075del p.R359Gfs*13 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- NCAM2 | c.2206_2212delinsCACTAG p.T736Hfs*2 | Nonsense Mutation (DEL) | VAF 28/153 reads (18%) | called by pindel, varscan2*
- NR2F2 | c.741_755del p.T248_L252del | In Frame Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- PEG3 | c.3945del p.Y1315* | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | called by mutect2, pindel*, varscan2
- QTRT1 | c.944C>G p.P315R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.138); called by mutect2, varscan2
- SERPIND1 | c.344del p.Q115Rfs*27 | Frame Shift Del (DEL) | VAF 33/126 reads (26%) | called by mutect2, pindel
- SIPA1L1 | c.3198_3200del p.N1066del | In Frame Del (DEL) | VAF 29/91 reads (32%) | called by mutect2, pindel, varscan2
- SOCS1 | c.296_298delinsT p.G99Vfs*17 | Frame Shift Del (DEL) | VAF 11/20 reads (55%) | called by pindel, varscan2*
- TMSB4X | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); called by mutect2, varscan2
- TMSB4X | c.29_34del p.I10_E11del | In Frame Del (DEL) | VAF 72/318 reads (23%) | called by mutect2, pindel, varscan2
- ABHD16B | c.1290G>C p.L430= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99410684; called by muse, mutect2, varscan2
- ACKR3 | c.690C>A p.V230= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV99799566; called by muse, mutect2, varscan2
- AKAP17A | c.84C>T p.T28= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV100002238; called by muse, mutect2, varscan2
- ANKRD17 | c.4032T>C p.A1344= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs1300860125, COSV100429198; called by muse, mutect2, varscan2
- ANO3 | c.663A>C p.A221= | Silent (SNP) | VAF 54/179 reads (30%) | catalogued as COSV99882805; called by muse, mutect2
- ATP10B | c.3531G>A p.L1177= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV100514948, COSV59163032; called by muse, varscan2
- BANP | c.606C>T p.V202= (on ENST00000286122; = p.V171= on NM_017869.4) | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99621532; called by muse, mutect2, varscan2
- BTBD3 | c.243G>A p.Q81= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV99655873; called by muse, mutect2
- C11orf87 | c.144G>A p.T48= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as rs558968039, COSV59356301; called by muse, mutect2, varscan2
- CD1A | c.675C>G p.V225= | Silent (SNP) | VAF 64/225 reads (28%) | catalogued as COSV99192362; called by muse, mutect2, varscan2
- COL14A1 | c.1131A>T p.P377= | Silent (SNP) | VAF 61/170 reads (36%) | catalogued as COSV99919266; called by muse, varscan2
- DGCR2 | c.1080C>T p.I360= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99593615; called by muse, mutect2, varscan2
- DNAH10 | c.1473C>T p.L491= (on ENST00000409039; = p.L430= on NM_207437.3) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV68991075; called by muse, mutect2, varscan2
- DSCAM | c.2325C>T p.D775= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs372175757, COSV68038264; called by muse, mutect2, varscan2
- DSCAM | c.150C>A p.G50= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV101260112; called by muse, mutect2, varscan2
- ENAH | c.954A>C p.P318= | Silent (SNP) | VAF 23/140 reads (16%) | catalogued as COSV99490639; called by muse, mutect2, varscan2
- ERCC6L | c.2355G>A p.E785= | Silent (SNP) | VAF 60/214 reads (28%) | catalogued as COSV100559108, COSV57819889; called by muse, mutect2, varscan2
- FAM120C | c.564G>A p.Q188= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100070045; called by muse, mutect2, varscan2
- FOXRED2 | c.1878G>C p.V626= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV53400835; called by muse, varscan2
- FREM2 | c.1119C>T p.T373= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs558517957, COSV99748732; called by muse, mutect2, varscan2
- GEMIN4 | c.2820C>G p.V940= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100021366; called by muse, mutect2, varscan2
- GPR183 | c.123C>G p.V41= | Silent (SNP) | VAF 37/162 reads (23%) | catalogued as COSV100854278; called by muse, mutect2, varscan2
- GRID1 | c.624C>T p.L208= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV60012078; called by muse, mutect2
- GRIN2B | c.3156C>T p.H1052= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as rs543452359, COSV101662963; called by muse, mutect2, varscan2
- GTPBP8 | c.854A>G p.*285= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV99868361; called by muse, mutect2, varscan2
- HERC2 | c.10722C>T p.S3574= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1332401512, COSV55327411; called by muse, mutect2, varscan2
- HMCN1 | c.2829G>A p.G943= | Silent (SNP) | VAF 29/157 reads (18%) | catalogued as COSV54882265; called by muse, mutect2, varscan2
- HSP90AB1 | c.765A>C p.S255= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV100807078; called by muse, mutect2, varscan2
- IFNA14 | c.231C>T p.I77= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as COSV101207310; called by muse, mutect2, varscan2
- INPP5D | c.2310A>G p.E770= (on ENST00000445964 / NM_001017915.3; = p.E769= on NM_005541.5) | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV100856793; called by muse, mutect2, varscan2
- INVS | c.2238C>T p.S746= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as COSV99317518, COSV99317726; called by muse, mutect2, varscan2
- IQCC | c.597G>A p.A199= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs201910762, COSV52208582; called by muse, mutect2, varscan2
- ISL1 | c.243G>A p.K81= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as COSV100045391; called by muse, mutect2, varscan2
- ITGB4 | c.4872G>A p.P1624= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs747577770, COSV99564008; called by mutect2, varscan2
- KCNK13 | c.528G>A p.L176= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV99965680; called by muse, mutect2, varscan2
- KDM3A | c.15C>T p.L5= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100460408; called by muse, mutect2, varscan2
- KMT2B | c.4014C>T p.C1338= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs770057861, COSV99719622; ClinVar: likely benign; called by muse, mutect2, varscan2
- KNTC1 | c.6453G>A p.K2151= | Silent (SNP) | VAF 53/180 reads (29%) | catalogued as COSV100338322; called by muse, mutect2, varscan2
- L1CAM | c.567G>A p.Q189= | Silent (SNP) | VAF 54/165 reads (33%) | catalogued as COSV100649131, COSV62829085; called by muse, mutect2, varscan2
- MANBA | c.1551C>T p.F517= (on ENST00000642252; = p.F471= on NM_005908.4) | Silent (SNP) | VAF 72/235 reads (31%) | catalogued as rs547084645, COSV99898706; called by muse, mutect2, varscan2
- MIS18BP1 | c.2619T>C p.G873= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV100172982; called by muse, mutect2, varscan2
- MYCBP2 | c.4962C>A p.T1654= (on ENST00000357337; = p.T1692= on NM_015057.5) | Silent (SNP) | VAF 58/193 reads (30%) | catalogued as COSV100630345; called by muse, mutect2, varscan2
- NFKBIA | c.477C>T p.S159= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs199877737, COSV99395130; called by muse, mutect2, varscan2
- NFKBIE | c.1209T>C p.S403= (on ENST00000275015; = p.S264= on NM_004556.3) | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs750515913, COSV99241104; called by muse, varscan2
- NRK | c.1485C>T p.S495= | Silent (SNP) | VAF 14/153 reads (9%) | catalogued as COSV54589996, COSV99687744; called by muse, mutect2, varscan2
- NUP62 | c.975C>T p.S325= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1190744786, COSV100352042; called by muse, mutect2, varscan2
- OR2A25 | c.24C>T p.I8= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as COSV101376384; called by muse, mutect2, varscan2
- OR2T35 | c.231C>A p.I77= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV100442269; called by muse, mutect2, varscan2
- PARD3B | c.2493C>A p.A831= (on ENST00000406610 / NM_001302769.2; = p.A762= on NM_057177.7) | Silent (SNP) | VAF 39/260 reads (15%) | catalogued as COSV100593417; called by muse, mutect2, varscan2
- PCDH11X | c.2964C>A p.P988= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as COSV100011673; called by muse, mutect2, varscan2
- PIFO | c.177C>T p.Y59= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs756815742, COSV100868617; called by muse, mutect2, varscan2
- PLXNC1 | c.291G>A p.A97= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV51570031; called by mutect2, varscan2
- POU3F4 | c.888T>C p.H296= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs774480747, COSV100937247; called by muse, mutect2, varscan2
- RASA4 | c.1039C>T p.L347= | Silent (SNP) | VAF 44/234 reads (19%) | catalogued as COSV99499996; called by muse, varscan2
- REC114 | c.624G>A p.T208= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs112737749, COSV58523833; called by muse, mutect2, varscan2
- REV3L | c.6867A>G p.K2289= | Silent (SNP) | VAF 26/182 reads (14%) | catalogued as rs767317558, COSV100725177; called by muse, varscan2
- RNASE3 | c.354G>A p.Q118= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV100484236, COSV58959463; called by muse, mutect2, varscan2
- RNFT1 | c.996C>T p.L332= | Silent (SNP) | VAF 56/132 reads (42%) | catalogued as COSV59870441; called by muse, mutect2, varscan2
- ROBO3 | c.3474C>T p.P1158= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100127596; called by muse, mutect2, varscan2
- RPL10L | c.252C>G p.G84= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100022563; called by muse, mutect2, varscan2
- RPL7 | c.375C>G p.L125= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV53584039; called by muse, mutect2, varscan2
- SELL | c.507C>T p.Y169= (on ENST00000650983; = p.Y156= on NM_000655.5) | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as COSV99357565; called by muse, mutect2, varscan2
- SGPL1 | c.1167C>T p.S389= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as rs771514224, COSV100940369; called by muse, mutect2, varscan2
- SLC22A4 | c.21G>A p.V7= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs762765767, COSV99569353; called by muse, mutect2, varscan2
- SLC4A1AP | c.225G>A p.K75= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV58133881; called by muse, mutect2, varscan2
- SPATS2L | c.405G>C p.S135= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs774982385, COSV100660697; called by muse, mutect2, varscan2
- SPTBN4 | c.2421C>A p.S807= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100150902; called by muse, mutect2, varscan2
- SULF1 | c.1458G>A p.R486= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99483025; called by muse, mutect2, varscan2
- SULT1B1 | c.328C>T p.L110= | Silent (SNP) | VAF 34/215 reads (16%) | catalogued as COSV100150258; called by muse, mutect2, varscan2
- TMPRSS6 | c.828C>T p.L276= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs1334496578, COSV100695753; called by muse, mutect2, varscan2
- TTC21A | c.3462G>A p.A1154= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs756540734, COSV99826877; called by muse, mutect2, varscan2
- TTC3 | c.2070T>C p.N690= | Silent (SNP) | VAF 85/335 reads (25%) | catalogued as COSV100695505; called by muse, mutect2, varscan2
- UMODL1 | c.3300C>T p.Y1100= (on ENST00000408910 / NM_001004416.2; = p.Y1228= on NM_173568.3) | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV101252564; called by muse, mutect2, varscan2
- ZFP28 | c.1842G>A p.E614= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as rs1018702341, COSV100019588; called by muse, mutect2, varscan2
- ZNF445 | c.2538G>T p.G846= | Silent (SNP) | VAF 70/222 reads (32%) | catalogued as COSV101253767; called by muse, mutect2, varscan2
- ZNF513 | c.831T>C p.H277= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1158950450, COSV99277607; called by muse, mutect2, varscan2
- AC245047.1 | n.4G>C | RNA (SNP) | VAF 95/562 reads (17%) | called by muse, varscan2
- CDCA7 | c.147+551A>G | Intron (SNP) | VAF 67/219 reads (31%) | catalogued as COSV100143517; called by muse, mutect2, varscan2
- PRB1 | c.101-1532C>A | Intron (SNP) | VAF 21/116 reads (18%) | catalogued as COSV99555893; called by muse, mutect2, varscan2
- RGS8 | c.-107G>T | 5'UTR (SNP) | VAF 66/206 reads (32%) | catalogued as COSV51122064; called by muse, mutect2, varscan2
- ZSCAN32 | c.915-198T>C | Intron (SNP) | VAF 22/121 reads (18%) | catalogued as COSV100514366; called by muse, mutect2
